Gene-level copy-number profile of tumor specimen TCGA-80-5608-01A from TCGA case TCGA-80-5608, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-80-5608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f4434eb0-fb54-4890-8e6d-741ec9914be5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-80-5608-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3c6705a6-f258-4797-ae54-db336478ba61

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 411; copy number 2: 17,711; copy number 3: 22,762; copy number 4: 9,817; copy number 5: 7,029; copy number 6: 506; copy number 7: 81; copy number 8: 1,428; copy number 9: 60; copy number 10: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-80-5608-01A-31D-1943-01): tumor purity 0.48, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,578 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:52,297,995–52,961,452, 10 genes, copy number 8: Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr6:127,968,785–128,520,616, 1 gene, copy number 10 (within-gene range 4–10): PTPRK.
- chr6:128,500,527–129,516,566, 8 genes, copy number 10 (within-gene range 6–10): AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1.
- chr8:48,710,789–145,066,685, 1,478 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr14:21,887,857–22,505,167, 81 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
